Somatic mutation profile of tumor specimen MP2PRT-PASLBF-TMP1-A (aliquot MP2PRT-PASLBF-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASLBF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (877 days).
Specimen MP2PRT-PASLBF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e66dae7-d5bf-40c5-b10c-17f3a3ff6154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLBF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLBF-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98b52309-c9a9-4546-812c-64af82bea871

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.12208G>A p.V4070I | Missense Mutation (SNP) | VAF 126/452 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs200943280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITSN1 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 180/464 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1251628654; called by muse, varscan2
- RHO | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 168/659 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs377687329, CM1212043; called by muse, mutect2, varscan2
- VCX3A | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.092); catalogued as rs373826288, COSV66910454; called by muse, varscan2
- IGKV1OR2-108 | chr2:113406854 AGGATTATACTACCCCATTCACAGTG>CACCCC | Missense Mutation (DEL) | VAF 62/284 reads (22%) | called by pindel, varscan2*
- ODF2 | c.1888A>T p.I630F (on ENST00000434106 / NM_153433.2; = p.I606F on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/507 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TRAJ28 | chr14:22515615 del ACTCTGTGCAT | Missense Mutation (DEL) | VAF 39/230 reads (17%) | called by pindel, varscan2
- FITM1 | c.459C>T p.F153= | Silent (SNP) | VAF 189/765 reads (25%) | catalogued as rs916639054, COSV52823907; called by muse, mutect2, varscan2
- TRAJ28 | c.12G>A p.G4= | Silent (SNP) | VAF 49/273 reads (18%) | catalogued as rs1217774668; called by muse, varscan2
